Gene-level copy-number profile of tumor specimen MP2PRT-PAPWCD-TMP1-A from MP2PRT case MP2PRT-PAPWCD, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.8 years (3,576 days).
Specimen MP2PRT-PAPWCD-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d2f702e6-9023-40a5-b397-98e78f9e8bcd.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PAPWCD-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,723 have no estimate.
https://portal.gdc.cancer.gov/files/143c67ca-ce4e-48c9-a006-4410da26955a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 3,050; copy number 2: 53,257; copy number 3: 902; copy number 4: 1,684; copy number 5: 3.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:11,869–14,409, 1 gene: DDX11L1.
- chr1:57,598–71,585, 2 genes: OR4G11P, OR4F5.
- chr1:89,551–91,105, 1 gene (within-gene range 0–1): AL627309.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:248,906,196–248,937,043, 3 genes, copy number 5: PGBD2, RNU6-1205P, RPL23AP25.

Autosomal genes at a single copy (total copy number 1): 194. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
